Gene-level copy-number profile of tumor specimen TCGA-DK-AA6M-01A from TCGA case TCGA-DK-AA6M, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 64.5 years (23,574 days).
Specimen TCGA-DK-AA6M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.cefa3de9-cda2-4618-861e-1c9e644885dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-AA6M-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40e944fa-d284-4777-9b6c-cec19a3e878d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,728; copy number 2: 45,797; copy number 3: 1,734; copy number 4: 1,561; copy number 5: 497; copy number 6: 48; copy number 7: 201; copy number 8: 100; copy number 9: 64; copy number 10: 47; copy number 11: 4; copy number 12: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-AA6M-01A-11D-A390-01): tumor purity 0.65, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 995 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–30,365,684, 453 genes, copy number 5–7 (broad region; genes not listed).
- chr5:31,193,686–43,412,391, 223 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:27,785,821–27,795,637, 1 gene, copy number 6 (within-gene range 3–6): AC090936.1.
- chr18:29,518,259–30,780,424, 6 genes, copy number 5–11: AC117569.1, AC117569.2, AC115100.1, MIR302F, AC090506.1, AC090506.2.
- chr20:37,903,111–41,618,384, 77 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr20:42,072,752–45,579,326, 98 genes, copy number 7–12 (within-gene range 4–12) (broad region; genes not listed).
- chr20:46,499,630–51,905,030, 125 genes, copy number 6–10 (within-gene range 1–10) (broad region; genes not listed).
- chr20:54,475,593–55,075,140, 3 genes, copy number 5: DOK5, RNU4ATAC7P, RPL12P4.
- chr20:59,113,224–59,516,039, 9 genes, copy number 9: MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1.

Autosomal genes at a single copy (total copy number 1): 9,675. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
